Somatic mutation profile of tumor specimen TCGA-BG-A18C-01A (aliquot TCGA-BG-A18C-01A-11D-A12J-09) from TCGA case TCGA-BG-A18C, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 72.8 years (26,602 days).
Specimen TCGA-BG-A18C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87692435-8f64-435d-ab1a-2f87d41ac219.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A18C-10A (Blood Derived Normal), aliquot TCGA-BG-A18C-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acad4d86-7e3b-47e1-8aaa-94980e9d8ab4

The open-access MAF lists 56 somatic variants for this specimen: 44 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 10, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 2, Frame Shift Del 2, In Frame Del 1, 3'UTR 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.315_320del p.G106_N107del | In Frame Del (DEL) | VAF 315/361 reads (87%) | hotspot (GDC flag); catalogued as COSV55925101; called by mutect2, pindel, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 164/223 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.8846-2A>G p.X2949_splice | Splice Site (SNP) | VAF 74/129 reads (57%) | catalogued as rs1553268594, CS1414654, COSV56367801; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs5030820, CM941383, CM941384, HX040002, COSV56545406, COSV56546550, COSV56572034; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAP3 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as rs369561716; called by muse, mutect2, varscan2
- ACTN3 | c.2353T>G p.F785V | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV59748629; called by muse, mutect2
- ADGRL2 | c.2531A>G p.E844G (on ENST00000370717 / NM_001366005.1; = p.E831G on NM_012302.4) | Missense Mutation (SNP) | VAF 191/516 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV54666224; called by muse, mutect2, varscan2
- ANXA7 | c.370+2T>A p.X124_splice | Splice Site (SNP) | VAF 52/118 reads (44%) | catalogued as COSV65823402, COSV65823473; called by muse, mutect2, varscan2
- BRCA2 | c.2553C>G p.F851L | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.059); catalogued as COSV66453535; called by muse, mutect2, varscan2
- CNIH1 | c.229C>A p.L77I | Missense Mutation (SNP) | VAF 73/124 reads (59%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV53594481; called by muse, mutect2, varscan2
- COL9A3 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.072); catalogued as rs752483618, COSV59651956; called by muse, mutect2, varscan2
- CSMD2 | c.6530A>T p.K2177M | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV53911113; called by muse, mutect2, varscan2
- CUTC | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as COSV65081793; called by muse, mutect2, varscan2
- DNAJC11 | c.158C>G p.S53* | Nonsense Mutation (SNP) | VAF 211/537 reads (39%) | catalogued as COSV53786569; called by muse, mutect2, varscan2
- DNAJC22 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.02); catalogued as rs201916155; called by muse, mutect2, varscan2
- DST | c.12103C>A p.L4035I (on ENST00000361203 / NM_001374722.1; = p.L1623I on NM_015548.5) | Missense Mutation (SNP) | VAF 115/244 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV55013772, COSV55021877; called by muse, mutect2, varscan2
- ERBB4 | c.2525G>A p.R842Q | Missense Mutation (SNP) | VAF 161/251 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1412193732, COSV100727674, COSV61486039; called by muse, mutect2, varscan2
- FAM131B | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs200621437, COSV58369761; called by muse, mutect2, varscan2
- FAM171A1 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs746109500, COSV65315964; called by muse, mutect2, varscan2
- FN1 | c.5854C>T p.R1952C | Missense Mutation (SNP) | VAF 58/71 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs781268073, COSV60552523; called by muse, mutect2, varscan2
- GRM5 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 97/234 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59604517; called by muse, mutect2, varscan2
- HSPA14 | c.135A>T p.E45D | Missense Mutation (SNP) | VAF 94/244 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV65684335; called by muse, mutect2, varscan2
- MEF2A | c.832T>C p.S278P (on ENST00000557942 / NM_001319206.2; = p.S280P on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.514); catalogued as COSV57533099; called by muse, mutect2, varscan2
- MIOX | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV53312914; called by muse, mutect2, varscan2
- MYO1A | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55653935; called by muse, mutect2
- MYO3A | c.3850dup p.T1284Nfs*7 | Frame Shift Ins (INS) | VAF 46/128 reads (36%) | catalogued as rs1340808362; called by mutect2, varscan2
- OPRK1 | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55570371; called by muse, mutect2, varscan2
- PCDHA7 | c.414G>C p.R138S | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs782512269, COSV65344050, COSV65345919, COSV65347426; called by muse, mutect2, varscan2
- PLXDC2 | c.254A>T p.D85V | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV65915948; called by muse, mutect2, varscan2
- RAD54B | c.1871T>A p.L624Q | Missense Mutation (SNP) | VAF 289/636 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as COSV60251162; called by muse, mutect2, varscan2
- RNF43 | c.1322del p.P441Lfs*61 | Frame Shift Del (DEL) | VAF 26/42 reads (62%) | catalogued as rs755967475, COSV68457961; called by mutect2, pindel, varscan2
- SLC2A4 | c.1498C>T p.L500F | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs1156577557, COSV50300916; called by muse, mutect2
- ST3GAL5 | c.209G>C p.C70S | Missense Mutation (SNP) | VAF 175/445 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV60385652; called by muse, mutect2, varscan2
- TASOR2 | c.4985C>G p.S1662* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as COSV60167412; called by muse, mutect2, varscan2
- TECTA | c.5672C>T p.T1891M | Missense Mutation (SNP) | VAF 220/509 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.626); catalogued as rs200977539; called by muse, mutect2, varscan2
- TRPM6 | c.6061C>A p.Q2021K | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV62509852; called by muse, mutect2
- TRPM6 | c.5056C>T p.L1686= | Splice Region (SNP) | VAF 9/222 reads (4%) | catalogued as COSV62509863, COSV62515168; called by muse, mutect2
- UACA | c.2644_2645del p.E882Ifs*9 | Frame Shift Del (DEL) | VAF 121/249 reads (49%) | catalogued as rs777766591; called by pindel, varscan2
- UPF1 | c.1820G>A p.R607Q (on ENST00000599848 / NM_001297549.2; = p.R596Q on NM_002911.4) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV53196455; called by muse, mutect2, varscan2
- VIM | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV56405759, COSV99813017; called by muse, mutect2, varscan2
- XIRP2 | c.2714C>T p.T905I (on ENST00000628543; = p.T1080I on NM_152381.6) | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs746431334, COSV54699430; called by muse, mutect2, varscan2
- ZDBF2 | c.1127A>G p.D376G | Missense Mutation (SNP) | VAF 168/221 reads (76%) | SIFT tolerated (0.4); PolyPhen benign (0.098); catalogued as COSV65625796, COSV65630091; called by muse, mutect2, varscan2
- ZFHX3 | c.7151C>T p.T2384I | Missense Mutation (SNP) | VAF 73/91 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs749012780, COSV51718103; called by muse, mutect2, varscan2
- CCAR2 | c.737dup p.Y247Lfs*40 | Frame Shift Ins (INS) | VAF 162/436 reads (37%) | called by pindel, varscan2
- ACOX2 | c.1458A>C p.P486= | Silent (SNP) | VAF 55/67 reads (82%) | catalogued as COSV57148946; called by muse, mutect2, varscan2
- ARHGEF7 | c.2190C>G p.L730= (on ENST00000375741 / NM_001113511.2; = p.L552= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 170/252 reads (67%) | catalogued as COSV54543044; called by muse, mutect2, varscan2
- CDH22 | c.1509C>T p.Y503= | Silent (SNP) | VAF 171/352 reads (49%) | catalogued as rs750004180, COSV64837515; called by muse, mutect2, varscan2
- IL6ST | c.2556T>C p.I852= | Silent (SNP) | VAF 78/205 reads (38%) | catalogued as COSV61141186; called by muse, mutect2, varscan2
- INTS11 | c.42C>T p.D14= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs1341068118, COSV59672260; called by muse, mutect2
- KANK2 | c.1392A>G p.Q464= | Silent (SNP) | VAF 29/37 reads (78%) | catalogued as COSV62007887; called by muse, mutect2, varscan2
- MROH2B | c.1059T>A p.I353= | Silent (SNP) | VAF 23/597 reads (4%) | catalogued as COSV68183945; called by muse, mutect2
- MS4A4A | c.579G>T p.V193= | Silent (SNP) | VAF 505/1092 reads (46%) | catalogued as COSV59701173; called by muse, mutect2, varscan2
- NUFIP2 | c.468G>A p.Q156= | Silent (SNP) | VAF 217/296 reads (73%) | catalogued as COSV56603375; called by muse, mutect2, varscan2
- SZT2 | c.4590G>A p.S1530= (on ENST00000634258 / NM_001365999.1; = p.S1473= on NM_015284.4) | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as rs771463235, COSV65169698; called by muse, mutect2, varscan2
- CARS1 | c.118-18C>T | Intron (SNP) | VAF 138/349 reads (40%) | catalogued as COSV53454183; called by muse, mutect2, varscan2
- DCK | c.*1T>G | 3'UTR (SNP) | VAF 136/333 reads (41%) | catalogued as COSV54378464, COSV54379744; called by muse, mutect2, varscan2
